Somatic mutation profile of tumor specimen HCM-BROD-0051-C64-86A (aliquot HCM-BROD-0051-C64-86A-01D-A85C-36) from HCMI case HCM-BROD-0051-C64, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 2.6 years (941 days).
Specimen HCM-BROD-0051-C64-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 23.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5851d23f-e75f-421d-9c2b-c00e7035cecd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0051-C64-10A (Blood Derived Normal), aliquot HCM-BROD-0051-C64-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbeab388-7959-43f4-b43b-b4deb5b3e376

The open-access MAF lists 26 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, Frame Shift Del 4, In Frame Del 3, 5'Flank 1, Nonsense Mutation 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 102/221 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CCAR2 | c.2594G>A p.R865Q | Missense Mutation (SNP) | VAF 48/1115 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as rs1207569395, COSV52384426; called by muse, mutect2
- CIB1 | c.440C>G p.S147C | Missense Mutation (SNP) | VAF 12/424 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.478); catalogued as COSV100153448; called by muse, mutect2
- GRB14 | c.978_980del p.E327del | In Frame Del (DEL) | VAF 166/374 reads (44%) | catalogued as rs755757465; called by pindel, varscan2
- KIF21B | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 343/700 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369827699; called by muse, mutect2, varscan2
- NEDD1 | c.1735C>T p.R579W | Missense Mutation (SNP) | VAF 189/399 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.65); catalogued as rs144557667; called by muse, mutect2, varscan2
- RIMS2 | c.4226G>A p.R1409H (on ENST00000666250 / NM_001348490.2; = p.R980H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/602 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1421932018, COSV99200810; called by muse, mutect2, varscan2
- BCOR | c.4187_4194del p.R1396Kfs*10 (on ENST00000378444 / NM_001123385.2; = p.R1362Kfs*10 on NM_017745.6) | Frame Shift Del (DEL) | VAF 172/186 reads (92%) | called by mutect2, pindel, varscan2
- CALD1 | c.1630_1633del p.G544Rfs*60 (on ENST00000361675 / NM_033138.4; = p.G289Rfs*60 on NM_004342.7) | Frame Shift Del (DEL) | VAF 233/542 reads (43%) | called by mutect2, pindel, varscan2
- HNRNPUL2 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 368/810 reads (45%) | SIFT tolerated (0.77); PolyPhen benign (0.007); called by muse, varscan2
- NETO2 | c.390_394del p.R131Nfs*8 | Frame Shift Del (DEL) | VAF 171/398 reads (43%) | called by mutect2, pindel, varscan2
- NFATC4 | c.375_383del p.E126_P128del | In Frame Del (DEL) | VAF 92/767 reads (12%) | called by mutect2, pindel
- NLRC5 | c.829C>G p.L277V | Missense Mutation (SNP) | VAF 272/577 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- RABL6 | c.1357_1359del p.G453del | In Frame Del (DEL) | VAF 288/629 reads (46%) | called by mutect2, pindel, varscan2
- RGL3 | c.215C>A p.A72E | Missense Mutation (SNP) | VAF 42/694 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); called by muse, mutect2
- SUCLG2 | c.1243G>T p.A415S | Missense Mutation (SNP) | VAF 166/359 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- THSD7B | c.2238G>A p.W746* | Nonsense Mutation (SNP) | VAF 16/362 reads (4%) | called by muse, mutect2
- UACA | c.286del p.T96Pfs*65 | Frame Shift Del (DEL) | VAF 127/308 reads (41%) | called by mutect2, pindel, varscan2
- ZMIZ1 | c.1924G>T p.G642C | Missense Mutation (SNP) | VAF 331/667 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKS6 | c.18G>A p.L6= | Silent (SNP) | VAF 269/537 reads (50%) | catalogued as rs1487517964; called by muse, mutect2, varscan2
- C4BPA | c.585C>T p.Y195= | Silent (SNP) | VAF 69/482 reads (14%) | catalogued as rs765449419, COSV100891306; called by muse, mutect2, varscan2
- CPNE2 | c.327C>T p.D109= | Silent (SNP) | VAF 25/458 reads (5%) | called by muse, mutect2
- ISLR2 | c.765G>A p.A255= | Silent (SNP) | VAF 355/718 reads (49%) | catalogued as COSV62301972; called by muse, mutect2, varscan2
- AGAP14P | n.1974A>T | RNA (SNP) | VAF 81/454 reads (18%) | called by muse, varscan2
- ARHGEF4 | chr2:130916225 C>T | 5'Flank (SNP) | VAF 355/733 reads (48%) | called by muse, mutect2, varscan2
- KLK12 | c.*92C>A | 3'UTR (SNP) | VAF 172/349 reads (49%) | called by mutect2, varscan2
